MMRF case MMRF_1373 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/82a77e5c-96f6-43a3-b3c0-7ca35f4983f4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.9 years (22,971 days); ISS stage: II; Days to last known disease status: 424 days (1.2 years); Days to last follow up: 424 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 1, day 424.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 781 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 333 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.16 mmol/L.
- Day 89: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.332 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 457 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6.82 mmol/L.
- Day 163 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.22 mg/dL; Immunoglobulin G 3.29 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.266 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.22 mmol/L.
- Day 219 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 3.09 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (1 sample)
- Sample MMRF_1373_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
